Surgical pathology report (de-identified scan), TCGA case TCGA-64-1677, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1677-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Lung Cancer

Source of Specimen(s):

- 1: Piece of 6th Rib Right
- 2: Wedge Resection Right Upper Lobe
- 3: RLL Check Bronchial Resection Margin
- 4: Level 7 Lymph Node
- 5: Level Right 4 Lymph Node
- 6: Level 10 Right Lymph Node
- 7: Level 3 Lymph Node

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled #1, "piece of right 6th rib"

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "piece of right 6th rib". It consists of a fragment of rib measuring 1.3 x 1.3 x 1.0 cm. It is bisected disclosing the usual bone with no suspicious lesions or masses. Entirely submitted in 1A, following decalcification.

Source of Tissue: 2. Labeled #2, "wedge resection right upper lobe"

Frozen Section Diagnosis: 2FS- SUBPLEURAL SCAR; NO TUMOR SEEN.

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "wedge resection right upper lobe". It consists of a wedge of dusky gray lung tissue measuring 5 x 2 x 1.5 cm. The specimen is received previously sectioned. Sections disclose an ill-defined area measuring 2.3 cm. The pleura in this area is somewhat thickened. No obvious lesions or masses are identified. One representative section was submitted for frozen section and the residue is submitted in 2FS. Additional tissue is submitted in 2A-2C.

Source of Tissue: 3. Labeled #3, "RLL"

Frozen Section Diagnosis: 3FS- LYMPH NODE ADJACENT TO BRONCHIAL MARGIN WITH METASTATIC CARCINOMA, ACTUAL MARGIN FREE OF TUMOR.

Gross Description: Received fresh in a container labeled with patient's

[page 2 of 3]
name and medical record number labeled "right lower lobe". It consists of a 224 gram dark-red lobe of lung measuring 17 x 9 x 7 cm. Half of the margin is procured for frozen section and the residue is submitted in 3FS. The diaphragmatic surface is unremarkable. Lateral and slightly inferior, there is a large area of pleura. Also in this area there is a marked area of fullness. Sections disclose a 4 x 4 x 3 cm pink firm tumor. The tumor is 4.5 cm from the margin. Elsewhere the pleura and remaining lung tissue is grossly unremarkable. At the hilum, the vascular margins are normal. The bronchial tree is opened and is grossly free of any tumor. A few hilar and peribronchial lymph nodes are found measuring up to 1 cm. A lymph node adjacent to the bronchial margin was submitted for frozen section.

Designation of Sections: 3A-3B- tumor in relationship to pleura, 3C- tumor in relationship to adjacent uninvolved lung tissue, 3D- vascular margins, 3E- hilar nodes, 3F- uninvolved lung tissue

Source of Tissue: 4. Labeled #4, "level 7 lymph node"

Frozen Section Diagnosis: 4FS- METASTATIC CARCINOMA.

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "level 7 lymph node". It consists of a few blackish-gray lymph nodes measuring collectively 1.2 x 1.0 x 0.6 cm. All of the tissue is entirely submitted and the residue is submitted in 4FS.

Source of Tissue: 5. Labeled #5, "level 4 lymph nodes"

Frozen Section Diagnosis: 5FS- NO TUMOR SEEN.

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "level 4 lymph nodes". It consists of a single grayish-black lymph node measuring 1.5 x 0.9 x 0.7 cm. Entirely submitted for frozen section and the residue is submitted in 5FS.

Source of Tissue: 6. Labeled #6, "level 10 lymph nodes"

Frozen Section Diagnosis: 6FS- NO TUMOR SEEN.

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "level 10 lymph nodes". It consists of a single grayish-black lymph measuring 0.9 x 0.8 x 0.7 cm. Entirely

[page 3 of 3]
submitted for frozen section and the residue is submitted in 6FS.

Source of Tissue: 7. Labeled #7, "level 3 lymph node"

Gross Description: Received fresh in a container labeled with patient's name and medical record number labeled "level 3 lymph node". It consists of a single black lymph node measuring 0.7 x 0.6 x 0.4 cm. Submitted in toto in 7A.

Final Diagnosis:

1. Portion of 6th rib, right, excision:
- No tumor seen.
2. Lung, right upper lobe wedge, excision:
- Subpleural scar, No tumor seen.
3. Lung, right lower lobe, lobectomy:
- Adenocarcinoma, acinar type, grade III (4 cm), invading visceral pleura.
- Bronchial and vascular margins negative for tumor.
- Inked parietal pleura margin negative for tumor.
- Metastatic adenocarcinoma in two of four lymph nodes (2/4).
- Uninvolved lung with mild emphysema.
4. Lymph node, level 7 (excision):
- Metastatic adenocarcinoma in one of five lymph nodes (1/5).
5. Lymph node, level 4 (excision):
- One lymph node, No tumor seen (0/1).
6. Lymph node, level 10 (excision):
- One lymph node, No tumor seen (0/1).
7. Lymph node, level 3 (excision):
- One lymph node, No tumor seen (0/1).

Stage: pT2,N2,Mx.

Source: NCI Genomic Data Commons file a87bf8a7-eceb-4d17-b5b8-33ca4dc7251c (TCGA-64-1677.31F047F0-DF34-44D4-B0D1-A3B43833F560.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).